Surgical pathology report (de-identified scan), TCGA case TCGA-YS-A95C, project TCGA-MESO (Mesothelioma), tissue source site Barretos Cancer Hospital, specimen TCGA-YS-A95C-01A (Primary Tumor).

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Pleura

- 1- Parietal pleura and right lung
Epithelioid mesothelioma infiltrating lung parenchyma, pleura and skeletal muscle.

Presence of angiolymphatic invasion
Absence of perineural invasion
Pleural margin involved by neoplasia
Bronchia margin uninvolved by neoplasia
- 2- Subcarinal node
Metastasis of mesothelioma in 4 lymph nodes of 4 dissected (4/4) with capsular transposition
- 3- Esophageal nodes
- 4- Metastasis of mesothelioma in 2 lymph nodes of 3 dissected (2/3) without capsular transposition

ICD-O3
Mesothelioma, epithelioid
malignant 9052/3
Site: (R) Pleura NOS
C68.4
JW 3/13/14

ICDAA Discrepancy		☒

Source: NCI Genomic Data Commons file 7ea03fb3-d9ab-495c-9efb-5760ec4e9331 (TCGA-YS-A95C.6067AFDB-9347-4212-BA91-FD839E999AEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).